TCGA case TCGA-2J-AABF — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Mayo Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/886d6116-d496-444f-9b7b-7449dad31055

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Dead; Days to death: 691 days (1.9 years); Cause of death: Cancer Related; Cause of death source: Medical Record.

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 73.7 years (26,936 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 691 days (1.9 years); Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 18; Tumor largest dimension diameter: 3.2 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 69 days; Days to treatment end: 244 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 96 days; Days to treatment end: 134 days; Treatment dose: 5,040 cGy; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Whipple.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Liver. Age at diagnosis: 75.0 years (27,379 days); Days to diagnosis: 443 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Liver. Age at diagnosis: 75.6 years (27,607 days); Days to diagnosis: 671 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 443 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 443 days (1.2 years); Evidence of progression type: Convincing Image Source.
- Day 671 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 671 days (1.8 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 691 days (1.9 years); Disease response: With Tumor.

Exposures
- Alcohol history: Yes; Alcohol intensity: Drinker; Alcohol drinks per day: 1; Alcohol days per week: 3.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 7.5; Tobacco smoking onset year: 1960; Tobacco smoking quit year: 1965.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2J-AABF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-2J-AABF-01A-03-TS3: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2J-AABF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2J-AABF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Tumor status: With tumor; Cause of death: Pancreatic Cancer; Tobacco smoking history indicator: 3; Alcohol exposure intensity: Weekly Drinker; Alcohol consumption frequency: 3; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Pancreatic Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 691 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 691 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 443 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2J-AABF-01A-31D-A40V-01): tumor purity 0.32, ploidy 1.92, whole-genome doublings 0.
